Gene-level copy-number profile of tumor specimen TCGA-EK-A2IP-01A from TCGA case TCGA-EK-A2IP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 28.3 years (10,347 days).
Specimen TCGA-EK-A2IP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.1bf1298b-4919-40d4-bfe5-d8aaa083a096.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2IP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e21be5c-b253-4b9f-a787-b576330cc899

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 6,542; copy number 2: 49,297; copy number 3: 1,881; copy number 4: 1,768; copy number 5: 148; copy number 6: 180.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2IP-01A-11D-A17U-01): tumor purity 0.84, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 316 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:89,107,621–89,590,097, 4 genes, copy number 6: EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr11:70,467,856–71,252,577, 1 gene, copy number 5 (within-gene range 4–5): SHANK2.
- chr11:70,603,304–71,639,769, 27 genes, copy number 5: AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, AP000867.4.
- chr17:74,670,077–77,920,258, 164 genes, copy number 6 (broad region; genes not listed).
- chr19:1,554,669–3,574,290, 111 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:4,621,194–4,785,077, 9 genes, copy number 5: AC011498.5, TNFAIP8L1, MYDGF, AC005339.1, DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3.

Autosomal genes at a single copy (total copy number 1): 6,513. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
